HCMI case HCM-BROD-1100-C84 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3bf3c1c9-413a-4013-8577-b7338a15c4f4

Demographics
Sex at birth: male; Race: white; Year of birth: 1940; Vital status: Dead; Days to death: 589 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Sezary syndrome: ICD-O-3 morphology code: 9701/3; ICD-10 code: C84.1; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 75.7 years (27,656 days); Tumor grade: GX; Prior malignancy: no; Prior treatment: Yes.
   Pathology details: Lymph node involved site: Axillary; Lymph nodes positive: 1; Lymph nodes tested: 1; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Alemtuzumab; Treatment intent type: Neoadjuvant; Days to treatment start: 117 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Brentuximab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 388 days (1.1 years); Days to treatment end: 477 days (1.3 years).
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Days to follow up: 589 days (1.6 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- TP53 mutation, nos (Targeted Sequencing): Positive; Amino-acid change: loss.
- Hemoglobin 14.5 g/dL.
- Leukocytes 11.5 ×10³/µL.
- Platelets 1114 ×10³/µL.
- Lactate Dehydrogenase 267.
- Hematocrit 44%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 83 kg; Height: 181 cm; BMI: 25.3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (1 sample)
- Sample HCM-BROD-1100-C84-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
